Surgical pathology report (de-identified scan), TCGA case TCGA-55-A493, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-A493-01A (Primary Tumor).

[page 1 of 4]
Results

GROSS AND MICROSCOPIC SURG.

Specimen Information

Collection Date and Time

Component Results

1CD-03

Adenocarcinoma, NOS
814013

Site: lung, upper lobe

DIAGNOSIS

Corrected report issued to correct the pathologist signature line.

9-11-12 RD

C34.1

A) LYMPH NODE, STATION 7, SUBCARINAL, BIOPSY: No evidence of malignancy (total of three nodes)

B) LYMPH NODE, STATION 4R, RIGHT PARATRACHEAL, BIOPSY: No evidence of malignancy (one lymph node)

C) LYMPH NODE, STATION 12, RIGHT UPPER LOBE BRONCHUS, BIOPSY: No evidence of malignancy (two lymph nodes)

D) LUNG, RIGHT UPPER LOBE, RESECTION: Nonsmall cell carcinoma compatible with adenocarcinoma, characterized by:

1. 3.2 cm in greatest dimension
2. Poorly differentiated
3. Negative for pleural involvement
4. Negative resection margin

LYMPH NODES, PERIBRONCHIAL, RESECTION WITH LOBE: No evidence of malignancy in a total of five lymph nodes

COMMENT:

A portion of the tumor, paranormal and normal tissue are banked for possible ancillary study.

Dr. Steeper evaluated the immunostains on block D4 only.

**** LUNG CANCER STAGING PARAMETERS*****

Case number: [REDACTED] Patient name: [REDACTED]

Final TNM: pT2aN0M0

2010 stage: IB

MACROSCOPIC

SPECIMEN TYPE

Lobectomy

TUMOR SITE

Right Lung-Upper Lobe

TUMOR SIZE

3.2 X 3 X 3 cm

TUMOR FOCALITY

Unifocal

MICROSCOPIC

HISTOLOGIC TYPE

Adenocarcinoma

HISTOLOGICAL GRADE

[page 2 of 4]
[REDACTED]

G3: (poorly differentiated) of G4
VISCERAL PLEURAL INVASION
Not identified
LYMPHATIC VASCULAR INVASION
Absent
TREATMENT EFFECT
Not applicable
MARGINS
Uninvolved by tumor

PATHOLOGIC STAGING
EXTENT OF INVASION

pT2a. (Tumor greater than 3 cm, but 5 cm or less in greatest dimension surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion more proximal than the lobar bronchus (ie, not in the main bronchus); or Tumor 5 cm or less in greatest dimension with any of the following features of extent: involves main bronchus, 2 cm or more distal to the carina; invades the visceral pleura; associated with atelectasis or obstructive pneumonitis that extends to the hilar region but does not involve the entire lung)

REGIONAL LYMPH NODES

pN0. (No regional lymph node metastasis)

Total nodes: 11

N1 nodes: 7

N1 positive nodes:

N2 nodes: 4

N2 positive nodes:

N2 sites sampled:

Station 7: Subcarinal nodes

Station 4: Lower paratracheal nodes

DISTANT METASTASIS

pM0. (No distant metastasis)

PATHOLOGIC STAGE Summary

Final TNM: pT2aN0M0

stage: IB

** The pathologic stage presumes no distant metastasis.

Case number: [REDACTED] Patient name: [REDACTED]

HISTOLOGIC TYPE

Adenocarcinoma

STAGE IV STATUS

No stage IV disease pathologically

TISSUE BLOCK AVAILABLE FOR ANCILLARY TESTING

D2-7

COMMENT

This patient's sample does not meet.

No fresh tissue is available for ancillary testing. The block identified above will be stored in pathology for 10 years for possible future ancillary testing. Please call any ancillary testing requests.

Attending Pathologist: [REDACTED]

CLINICAL INFORMATION

[REDACTED]

[page 3 of 4]
[REDACTED]

Right upper lobe lung mass

SPECIMEN/GROSS DESCRIPTION

A) SOURCE: Lymph node biopsy, #7 subcarinal

The specimen is received labeled "#7 subcarinal lymph node." It consists of three focally gray-black apparent lymph nodes with a small amount of focally attached adipose tissue. Lymph node #1 measures 0.5 x 0.4 x 0.3 cm. Lymph node #2 measures 1 x 0.7 x 0.3 cm and lymph node #3 measures 2.5 x 0.6 x 0.3 cm with focally attached fat included. Tissue is submitted in toto for frozen section diagnosis in one block.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Negative." is rendered by [REDACTED]

B) SOURCE: Lymph node biopsy, #4R right paratracheal

The specimen is received labeled "#4R right paratracheal lymph node." It consists of a 2 x 1 x 0.5 cm portion of fibrofatty tissue which contains one gray-black possibly focally disrupted lymph node measuring 1.6 x 1 x 0.3 cm. The apparent lymph node is submitted in toto for frozen section diagnosis on one block.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Negative." is rendered by [REDACTED]

[REDACTED]

C) SOURCE: Lymph node biopsy, rt upper lobe #12, bronchus

The specimen is received labeled "Rt upper lobe bronchus lymph node #12." It consists of two lymph nodes measuring 0.4 and 1 cm in greatest dimension. The large lymph node is serially sectioned and both nodes are entirely submitted in two cassettes.

D) SOURCE: Lung, right upper lobe

The specimen is received fresh from the OR labeled "right upper lobe." It consists of a 147 gram spongy red-tan lung lobe measuring 15 x 8 x 4.5 cm. The pleura is smooth, focally firm (inked blue). The medial aspect displays two surgical staple lines measuring 4.8 and 5.5 cm in length. The sutures are removed and underlying parenchyma inked black. The inked aspect of the pleura is incised to display a large rubbery tumor. A representative section of the tumor and entire en face bronchial margin are frozen on two blocks.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "FS1: Margin negative. FS2: Non-small cell carcinoma, favor squamous cell." is rendered by [REDACTED]

The tissue is serially cross-sectioned. On cut surface, the tumor is approximately 2.7 cm from the bronchial margin and 2 cm from the superiorly located surgical staple line. The tumor focally abuts inked pleural surfaces. Extension through the pleura is not grossly seen.

On sectioning, the tumor measures 3.2 x 3 x 3 cm and has tan, glistening focally gray-black cut surfaces. The tumor grossly obliterates small apparent vessels and possible bronchioles.

The remaining cut surfaces are mottled pink-red with scattered black patchy discolored foci. No other lesions are seen. The cut surfaces display four black lymph nodes measuring between 0.6 and 2.3 cm in greatest diameter.

Note: A portion of the tumor, paraneoplastic and normal tissue are banked for possible ancillary study.

[REDACTED]

[page 4 of 4]
Note: Specimen removed from patient at _____ Specimen placed
in 10% neutral buffered formalin at _____ Specimen fixed in
formalin for a minimum of 6 hours, and not longer than 48 hours.

Representative sections are submitted in a total of 16 cassettes labeled:

- D1. Frozen section residue, en face bronchial margin
2. Frozen section residue, tumor
- 3-7. Tumor to include blue-inked pleura and adjacent grossly obliterated vasculature and bronchioles
8. En face vasculature
9. Black ink subjacent to the staple line closest to the tumor
10. Black ink subjacent to the staple line furthest from the tumor
11. Apical aspect
12. Lingular aspect
13. Two nodes, one is inked blue
- 14-15. One node
16. One node

This case is accessioned in _____

Gross dictation by _____

MICROSCOPIC

A-D) The microscopic appearance substantiates the diagnosis.

D) Block D4 was evaluated with immunostains in order to further characterize this nonsmall cell carcinoma. Results are as follows:

TTF-1: Strongly positive, nuclear pattern

P63: negative

These results are compatible with adenocarcinoma of pulmonary origin.

Dictation by _____

Interpreted at _____

COLLECTED: _____

ACCESSIONED: _____

SIGNED: _____

Lab and Collection

GROSS AND MICROSCOPIC SURGICAL PANEL
Information

Lab and Collection

Result History

GROSS AND MICROSCOPIC SURGICAL PANEL
Report

Order Result History

Lab Status

Order Complete

Result Information

Result Date and Time

Status

Provider Status

Lab Information

Reviewed (initials)	_____	_____

8/30/12

Source: NCI Genomic Data Commons file 33ce6842-08ee-4909-8bdc-9d224e84ff54 (TCGA-55-A493.B22D9414-01C4-4042-97E5-3C8B2DF9AD97.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).